Surgical pathology report (de-identified scan), TCGA case TCGA-KO-8411, project TCGA-KICH (Kidney Chromophobe), tissue source site MD Anderson Cancer Center, specimen TCGA-KO-8411-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

CHROMOPHOBE RENAL CELL CARCINOMA, FUHRMAN'S NUCLEAR GRADE 3. (SEE COMMENT)

TUMOR MEASURES 5.0 CM IN MAXIMUM DIMENSION.

FOCAL LYMPHATIC/VASCULAR INVASION IDENTIFIED.

Multilocular cyst. (4.0 cm)

Margins of resection free of tumor.

COMMENT

Immunoperoxidase studies demonstrate the tumor cells to be positive for CK7 and negative for CD10 and Vimentin, supporting the diagnosis of Chromophobe renal cell carcinoma. The tumor has a pushing border but does not invade the sinus adipose tissue or perinephric fat. The renal vein is free of tumor.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A nephrectomy specimen (15.0 x 10.0 x 8.0 cm) including the kidney (10.0 x 6.0 x 5.0 cm) and attached ureter (9.0 cm in length).

Located in the mid-portion of the kidney there is a orange-brown homogeneous tumor measuring 5 x 4 x 4 cm. The tumor appears grossly to be confined to the kidney. No invasion of the renal vein is identified.

Located in the inferior pole of the kidney (0.5 cm from the main mass) is a large multilocular cyst (4.0 x 3.0 x 3.0 cm) containing clear fluid. The cyst has a thin capsule and smooth lining.

SECTION CODE: A1, vascular and ureteric resection margin, en face; A2-A7, tumor with adjacent kidney; A8, A9, tumor with adjacent renal sinus; A10-A14, renal cysts with adjacent renal parenchyma and small portion of tumor in cassette A10; A15, renal pelvis; A16, normal kidney. SQ/msm

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

Source: NCI Genomic Data Commons file 01192b42-c386-43af-961c-9d6b28670770 (TCGA-KO-8411.C494BA8D-1E0E-420A-B513-DBBAC8F72994.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).